Somatic mutation profile of tumor specimen TCGA-FI-A2CY-01A (aliquot TCGA-FI-A2CY-01A-11D-A17D-09) from TCGA case TCGA-FI-A2CY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,098 days).
Specimen TCGA-FI-A2CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0326da15-5e3e-4469-9e3c-4805a78a337d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2CY-10A (Blood Derived Normal), aliquot TCGA-FI-A2CY-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2a7254f-c648-4dd1-9e23-9d9f21b6068f

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>C p.G423A (on ENST00000281708 / NM_001349798.2; = p.G343A on NM_018315.5) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- TP53 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 21/35 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138009, CM161671, COSV52675572, COSV52699845, COSV52722122; called by muse, mutect2, varscan2
- ADAMTSL5 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100389169; called by muse, mutect2, varscan2
- AGMAT | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV101011785; called by muse, mutect2
- BAZ1A | c.1768C>A p.R590S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100701154, COSV62408893; called by muse, mutect2
- COLGALT2 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100730680; called by muse, mutect2, varscan2
- CPNE9 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as COSV99808290; called by muse, mutect2, varscan2
- CSMD3 | c.3209A>G p.D1070G (on ENST00000297405 / NM_001363185.1; = p.D966G on NM_052900.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.887); catalogued as COSV99835275; called by muse, mutect2, varscan2
- ENOPH1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs374821138, COSV56731780; called by muse, mutect2, varscan2
- FBXO17 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.239); catalogued as COSV99494134; called by muse, mutect2, varscan2
- FPR1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 81/127 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs138475342, COSV100493915; called by muse, mutect2, varscan2
- FREM2 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs1297393111, COSV54857638; called by muse, mutect2, varscan2
- GPR161 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.034); catalogued as COSV99606674; called by muse, mutect2, varscan2
- GSTCD | c.1234A>T p.K412* (on ENST00000360505 / NM_001031720.3; = p.K325* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as COSV100853841; called by muse, mutect2, varscan2
- KCNA3 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871265; called by muse, mutect2, varscan2
- KIAA0319 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772701496, COSV100985224, COSV100985589; called by muse, mutect2, varscan2
- LRP1 | c.12436G>A p.E4146K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as rs773620729, COSV54503705; called by muse, mutect2, varscan2
- MNT | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0.351); catalogued as COSV99438092; called by muse, mutect2, varscan2
- RBM15B | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1553621975, COSV100082163; called by muse, mutect2
- SLC22A2 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.034); catalogued as COSV100870987; called by muse, mutect2, varscan2
- TGFBR3 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs757667211, COSV99283004; called by muse, varscan2
- TSHZ3 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 42/1694 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV53666080; called by muse, mutect2
- XKR5 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV68398628; called by muse, mutect2, varscan2
- ZDHHC19 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs773350192, COSV56349749; called by muse, varscan2
- ZMYM2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1220085969, COSV101243818; called by muse, mutect2, varscan2
- NCAM2 | c.1929del p.V644Cfs*61 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- PCDH11X | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARMC12 | c.735G>A p.G245= (on ENST00000373866 / NM_001286574.2; = p.G272= on NM_145028.5) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99849466; called by muse, mutect2, varscan2
- CBWD5 | c.54T>C p.D18= | Silent (SNP) | VAF 148/572 reads (26%) | catalogued as rs201229881, COSV101070723; called by muse, mutect2, varscan2
- CGNL1 | c.3270G>A p.R1090= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs367704165; called by muse, mutect2, varscan2
- CHIA | c.555T>C p.A185= (on ENST00000343320; = p.A77= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100588679, COSV58479245; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.468C>T p.T156= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV101236926; called by muse, mutect2, varscan2
- HOXB6 | c.141G>A p.P47= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV53313002; called by muse, mutect2, varscan2
- LTF | c.732C>T p.D244= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs141357150, COSV99211663; called by muse, mutect2, varscan2
- RHEX | c.81C>T p.T27= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs781826558, COSV100520138; called by muse, mutect2, varscan2
- SLC45A1 | c.993C>T p.A331= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV99238963; called by muse, varscan2
- SON | c.2307C>T p.S769= | Silent (SNP) | VAF 13/332 reads (4%) | catalogued as COSV99278542; called by muse, mutect2
- TNIK | c.3954T>C p.H1318= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as COSV99457460; called by muse, mutect2, varscan2
- GZF1 | c.*1G>C | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100582551; called by muse, mutect2, varscan2
